ALCHEMIST case ALCH-B0CP — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3d5c0f0e-eb8a-44f4-8baa-41f490d2d2d5

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 64.6 years (23,581 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B0CP-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B0CP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B0CP-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 34; Percent tumor nuclei: 75; Percent normal cells: 11; Percent necrosis: 43; Percent stromal cells: 12; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 0.
